Somatic mutation profile of tumor specimen C3N-02000-01 (aliquot CPT0109680010) from CPTAC case C3N-02000, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 46.3 years (16,924 days).
Specimen C3N-02000-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c22544a4-2bed-41a0-90d7-c7486c6b558a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02000-71 (Blood Derived Normal), aliquot CPT0139090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dff4b61-3062-4bc4-961f-cce15088bfae

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Frame Shift Del 3, Intron 2, RNA 1, Nonsense Mutation 1, 5'Flank 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.537T>G p.H179Q | Missense Mutation (SNP) | VAF 65/187 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs876660821, CM0910925, COSV52669519, COSV52673406, COSV53016879; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ELAPOR1 | c.994_997del p.D332Kfs*36 | Frame Shift Del (DEL) | VAF 42/243 reads (17%) | catalogued as rs1296480808; called by mutect2, pindel, varscan2
- PIK3C2B | c.3508T>G p.Y1170D | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915990; called by muse, mutect2, varscan2
- PPFIA2 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV61043023; called by muse, mutect2
- PRSS12 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367921225; called by muse, mutect2, varscan2
- CD4 | c.792del p.K264Nfs*49 | Frame Shift Del (DEL) | VAF 41/223 reads (18%) | called by mutect2, pindel, varscan2
- CDC16 | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- ECH1 | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELF3 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2
- FAM90A1 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 35/658 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- MIER3 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MUC5B | c.8842G>A p.E2948K | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MYT1 | c.1565A>T p.H522L | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2
- OR1N2 | c.872T>G p.F291C | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARP4 | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- PCDHB8 | c.2272G>T p.G758* | Nonsense Mutation (SNP) | VAF 54/279 reads (19%) | called by muse, mutect2, varscan2
- PLA2G5 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- REV1 | c.1654del p.T552Hfs*23 | Frame Shift Del (DEL) | VAF 79/220 reads (36%) | called by mutect2, pindel, varscan2
- SLC5A7 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLCO4A1 | c.1639-6_1639-3del | Splice Region (DEL) | VAF 126/381 reads (33%) | called by mutect2, pindel, varscan2
- ST14 | c.2291A>G p.Q764R | Missense Mutation (SNP) | VAF 17/391 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THRAP3 | c.217T>A p.F73I | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ABCD3 | c.696C>T p.S232= | Silent (SNP) | VAF 10/267 reads (4%) | called by muse, mutect2
- APOB | c.13584C>T p.Y4528= | Silent (SNP) | VAF 26/225 reads (12%) | catalogued as rs1490771906, COSV51926654; called by muse, mutect2, varscan2
- FAM90A1 | c.1098C>T p.S366= | Silent (SNP) | VAF 44/708 reads (6%) | called by muse, mutect2
- PADI4 | c.1854C>T p.S618= | Silent (SNP) | VAF 27/203 reads (13%) | catalogued as rs1402958415; called by muse, mutect2, varscan2
- PCDHGA12 | c.1755C>A p.G585= | Silent (SNP) | VAF 14/430 reads (3%) | called by muse, mutect2
- SLC12A4 | c.558T>C p.Y186= | Silent (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- STAM2 | c.759C>T p.S253= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as rs1395737153; called by muse, mutect2
- ZFP36L1 | c.675C>T p.S225= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as rs1459103351; called by muse, mutect2, varscan2
- AC244517.10 | c.36-8719T>A | Intron (SNP) | VAF 54/346 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504607 del TTTG | 5'Flank (DEL) | VAF 21/255 reads (8%) | called by mutect2, pindel
- COG6 | c.*256C>A | 3'UTR (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- LINC01159 | n.123G>A | RNA (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- RMDN1 | c.248-6262C>T | Intron (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
